Somatic mutation profile of tumor specimen TCGA-CH-5769-01A (aliquot TCGA-CH-5769-01A-11D-1576-08) from TCGA case TCGA-CH-5769, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.8 years (17,807 days).
Specimen TCGA-CH-5769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49be23db-fe80-46c2-a01e-c17e28c10380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5769-11A (Solid Tissue Normal), aliquot TCGA-CH-5769-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4583045d-ea25-4c8e-82ba-ef8817bd6ee5

The open-access MAF lists 95 somatic variants for this specimen: 65 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 27, Frame Shift Del 5, Nonsense Mutation 3, Intron 2, Frame Shift Ins 2, Splice Site 1, Translation Start Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.496); catalogued as rs904940190, COSV57078691; called by muse, mutect2
- ALPK2 | c.1566_1567insG p.K523Efs*50 | Frame Shift Ins (INS) | VAF 51/279 reads (18%) | catalogued as rs763053514, COSV64496000; called by mutect2, pindel*, varscan2
- APPL1 | c.1985A>T p.D662V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55703566; called by muse, mutect2
- ARHGAP45 | c.420C>T p.D140= | Splice Region (SNP) | VAF 13/179 reads (7%) | catalogued as rs3764655, COSV54037138; called by muse, mutect2
- ASB4 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57948168; called by muse, mutect2
- BOD1L1 | c.4366A>G p.K1456E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50062406; called by muse, mutect2
- C20orf96 | c.209C>T p.T70M (on ENST00000360321 / NM_153269.3; = p.T69M on NM_080571.1) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs768337298, COSV64404544; called by muse, mutect2
- CAMTA1 | c.806-1G>T p.X269_splice | Splice Site (SNP) | VAF 56/329 reads (17%) | catalogued as COSV57925824; called by muse, mutect2, varscan2
- CDK13 | c.1104del p.S369Afs*75 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1183149998; called by mutect2, pindel
- CDR2 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as rs145715358; called by muse, mutect2, varscan2
- CLPTM1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs1468782536, COSV61612227; called by muse, mutect2, varscan2
- COL4A2 | c.4321G>T p.G1441* | Nonsense Mutation (SNP) | VAF 13/149 reads (9%) | catalogued as COSV64633980; called by muse, mutect2
- COL6A3 | c.5653G>A p.V1885M | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780597629, COSV55108926, COSV99796161; called by muse, mutect2, varscan2
- CYTH3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs749850896, COSV63438103; called by muse, mutect2, varscan2
- DDX23 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.614); catalogued as COSV57285813; called by muse, mutect2
- DHRSX | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs775240585, COSV58138765; called by muse, mutect2
- DNAH9 | c.13130A>C p.Q4377P | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV52376033; called by muse, mutect2
- DNMT1 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV61577509; called by muse, mutect2
- FAM214A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55923866, COSV55927128; called by muse, mutect2
- FAM91A1 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58239825; called by muse, mutect2, varscan2
- FILIP1 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV52740431; called by muse, mutect2, varscan2
- GBP3 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 27/201 reads (13%) | catalogued as COSV52520021; called by muse, mutect2, varscan2
- GMIP | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV52559851; called by muse, mutect2, varscan2
- GRIK1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1044952678, COSV58731591; called by muse, mutect2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | catalogued as rs755016625; called by mutect2, varscan2
- IGSF9B | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs780048209, COSV58072648; called by muse, mutect2
- ITGA11 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs189643766; called by muse, mutect2, varscan2
- KCNG2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV60268968; called by muse, mutect2, varscan2
- KCNH5 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 15/251 reads (6%) | catalogued as COSV59777295; called by muse, mutect2
- KMT2A | c.6185G>A p.R2062H | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63291640; called by muse, mutect2
- LAMC1 | c.4338A>C p.E1446D | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51176405; called by muse, mutect2, varscan2
- LRIT3 | c.1799G>C p.C600S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV59987603; called by muse, mutect2
- MRGPRX2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs779903448, COSV61674935; called by muse, mutect2
- MUC16 | c.42460G>T p.G14154C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66695933; called by muse, mutect2, varscan2
- MYO15A | c.5279C>A p.S1760Y | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99233990; called by muse, mutect2
- MYO1D | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1234216512, COSV59023168; called by muse, mutect2
- MYT1L | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV67732181; called by muse, mutect2, varscan2
- NUP188 | c.4869G>T p.E1623D | Missense Mutation (SNP) | VAF 19/347 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs1389577675, COSV65331896; called by muse, mutect2
- PCDHA13 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV56543839; called by muse, mutect2
- PCDHA2 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782465720, COSV65368209; called by muse, mutect2
- PLD1 | c.1060T>C p.W354R | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60574000; called by muse, mutect2
- PPP1R3B | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60100221; called by muse, mutect2, varscan2
- PRDM2 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs143566559; called by muse, mutect2
- RAI1 | c.4891G>A p.A1631T | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55398988; called by muse, mutect2
- SARS1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.374); catalogued as rs776627242, COSV52323180; called by muse, mutect2
- SEPTIN9 | c.272G>A p.R91Q (on ENST00000427177 / NM_001113491.2; = p.R73Q on NM_006640.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); catalogued as rs764983438, COSV61201901; called by muse, mutect2, varscan2
- SLC35D2 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV53564732; called by muse, mutect2
- SLC49A3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138706049; called by muse, mutect2
- SLC5A10 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1215372222, COSV58761970; called by muse, mutect2, varscan2
- SMPD3 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs200081668, COSV54715870; called by muse, mutect2, varscan2
- ST6GAL1 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV51474981; called by muse, mutect2
- TCF7L2 | c.1627del p.L543Wfs*6 (on ENST00000355995 / NM_001367943.1; = p.L520Wfs*6 on NM_030756.5) | Frame Shift Del (DEL) | VAF 45/226 reads (20%) | catalogued as rs1193915978, COSV53337648; called by mutect2, pindel, varscan2
- TLK1 | c.1481G>T p.R494I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV62632923; called by muse, mutect2
- TRPV4 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55685469; called by muse, mutect2
- VKORC1L1 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs768279578, COSV62490327; called by muse, mutect2, varscan2
- VPS13B | c.3317G>A p.G1106E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62156482; called by muse, mutect2
- WNT9A | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV55297172; called by muse, mutect2, varscan2
- ZBTB32 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV52892509; called by muse, mutect2
- ZNF462 | c.3392T>C p.V1131A | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as COSV52950564; called by muse, mutect2
- ZNF71 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs374291976; called by muse, mutect2, varscan2
- ANKRD6 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP15 | c.1076del p.F359Sfs*33 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | called by mutect2, pindel, varscan2
- KANK4 | c.349del p.Q117Rfs*9 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- SLC25A25 | c.619dup p.L207Pfs*59 | Frame Shift Ins (INS) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- TMEM43 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); called by muse, mutect2
- ADNP2 | c.3273T>C p.F1091= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV51539320, COSV51542299; called by muse, mutect2
- ALG2 | c.594C>T p.V198= | Silent (SNP) | VAF 16/143 reads (11%) | catalogued as rs201757938, COSV53060801; called by muse, mutect2, varscan2
- ARNT2 | c.2052C>T p.F684= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as COSV57590440; called by muse, mutect2
- BEND3 | c.1719C>T p.F573= | Silent (SNP) | VAF 9/181 reads (5%) | catalogued as rs370245100, COSV64682257; called by muse, mutect2
- BMP1 | c.1305C>T p.C435= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs538422794, COSV60481822; called by muse, mutect2, varscan2
- CACNG4 | c.672G>A p.A224= | Silent (SNP) | VAF 33/181 reads (18%) | catalogued as rs377684890; called by muse, mutect2, varscan2
- CASKIN1 | c.597C>T p.N199= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as rs376282628; called by muse, mutect2, varscan2
- DGLUCY | c.795T>C p.C265= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV56365943, COSV56370161; called by muse, mutect2
- DIS3L | c.2001C>T p.H667= (on ENST00000319212 / NM_001143688.3; = p.H584= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs1404434525, COSV59914372; called by muse, mutect2
- DISC1 | c.651T>C p.L217= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV54418491; called by muse, mutect2
- DLGAP2 | c.1920C>T p.D640= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs373983764; called by muse, mutect2, varscan2
- FLNA | c.4290C>T p.G1430= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1557177449, COSV61051316; called by muse, mutect2, varscan2
- FZD2 | c.1047G>A p.S349= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as rs901265781, COSV59530189; called by muse, mutect2
- IVNS1ABP | c.1471T>C p.L491= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs979539083, COSV62252085; called by muse, mutect2, varscan2
- LIG4 | c.2166G>A p.K722= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs1313749170, COSV63598062; called by muse, mutect2
- MFAP5 | c.222C>A p.S74= | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as rs1277498625, COSV63946321; called by muse, mutect2
- MSI2 | c.303G>A p.A101= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as rs574167789, COSV52359594; called by muse, mutect2
- OBSCN | c.5019C>T p.R1673= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs375439636; called by muse, mutect2
- OR2A25 | c.255G>A p.L85= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV68717666; called by muse, mutect2
- PCDHA4 | c.1869C>T p.R623= | Silent (SNP) | VAF 11/233 reads (5%) | catalogued as rs782158159, COSV63543046; called by muse, mutect2
- RAB3A | c.138G>A p.S46= | Silent (SNP) | VAF 44/336 reads (13%) | catalogued as rs144222621, COSV55852508, COSV55853842; called by muse, mutect2, varscan2
- SCARA5 | c.852C>T p.T284= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1185099224, COSV100108034, COSV57281382; called by mutect2, varscan2
- SERPINA10 | c.264A>G p.R88= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV56229679; called by muse, mutect2, varscan2
- SV2A | c.72G>A p.K24= | Silent (SNP) | VAF 39/184 reads (21%) | catalogued as COSV64964835; called by muse, mutect2, varscan2
- TUBG2 | c.126C>T p.T42= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV52219590; called by muse, mutect2
- UBR3 | c.5662C>T p.L1888= | Silent (SNP) | VAF 9/144 reads (6%) | catalogued as COSV55860085; called by muse, mutect2
- ZBTB21 | c.2025C>T p.C675= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as rs143540135, COSV60403692; called by muse, mutect2
- BX119917.1 | n.186C>T | RNA (SNP) | VAF 10/68 reads (15%) | catalogued as rs754522531; called by muse, mutect2, varscan2
- DOT1L | c.4606+1114C>T | Intron (SNP) | VAF 5/101 reads (5%) | catalogued as rs1436602814, COSV58537056; called by muse, mutect2
- GALNT10 | c.568+17425G>A | Intron (SNP) | VAF 14/83 reads (17%) | catalogued as COSV51734037; called by muse, mutect2, varscan2
